Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A619, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A619-01A (Primary Tumor).

Pathology report for

Discussion:

Numerous MIB-1 reactive cells are present throughout the specimen. In the most proliferative areas, a labeling index of 9.6 percent is calculated. This high level, combined with the borderline mitotic count warrants classification as anaplastic/grade III.

Diagnosis:

Anaplastic oligodendroglioma, grade III

- MIB-1 LI = 9.6%

*ICD-O-3
Oligodendroglioma, anaplastic
9451/3
Site: Supratentorial NDS C71.0
JW 4/16/13*

Microscopic Description:

Microscopic examination of frozen section and permanent material reveals a glial neoplasm composed of a proliferation of cells with prominent perinuclear halos. Overall, the tumor cell population demonstrates moderate nuclear atypia and a paucity of fibrillary processes, with occasional cells showing more pronounced atypia. Up to 3 mitotic figures per 10 high power fields are encountered. Neither necrosis nor microvascular proliferation are identified. The tumor infiltrates both the white and grey matter. There is background hemorrhage and scattered calcifications. Foreign surgical material is focally encountered. The histologic features are consistent with an oligodendroglioma.

Dual Symptomatic Primary Notes		
Care is (in the):	QUALIFIED	UNQUALIFIED
Reviewed Initials	MB	

Source: NCI Genomic Data Commons file 37e696d6-a1aa-4d25-8dcb-36e1ba892440 (TCGA-HT-A619.1425BF47-215A-486A-BA84-73E0F3F34A57.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).